Gene-level copy-number profile of tumor specimen BLGSP-71-08-00199-01A from CGCI case BLGSP-71-08-00199, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Alive; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 14.2 years (5,177 days).
Specimen BLGSP-71-08-00199-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Abdomen; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ec81c636-3fe9-44a4-a67d-19c9da594558.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-08-00199-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/60e7a722-e761-4f31-b698-09d5dbf975fc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 97; copy number 1: 2,919; copy number 2: 52,655; copy number 3: 3,231.

Homozygous deletions (total copy number 0; autosomes only): 97 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,851,705–106,258,223, 67 genes (within-gene range 0–2) (broad region; genes not listed).
- chr21:7,744,962–8,680,934, 28 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2.
- chr22:38,952,741–38,992,804, 2 genes (within-gene range 0–2): APOBEC3A, APOBEC3B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 63. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
